Somatic mutation profile of tumor specimen MMRF_1761_1_BM_CD138pos (aliquot MMRF_1761_1_BM_CD138pos_T2_KBS5U_K11929) from MMRF case MMRF_1761, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.8 years (24,392 days).
Specimen MMRF_1761_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf76d11b-ebb1-4d41-980c-5ab327566435.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1761_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1761_1_PB_Whole_C7_KBS5U_K11912; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36d975e5-27f2-4c04-b82d-9e56cc5b4e1d

The open-access MAF lists 84 somatic variants for this specimen: 33 protein-altering or splice-affecting, 6 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, 3'UTR 27, Intron 10, Silent 6, 5'UTR 4, 3'Flank 2, 5'Flank 2, Nonsense Mutation 2, Splice Region 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD6 | c.815C>A p.S272Y | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs770225510; called by muse, mutect2, varscan2
- CLNS1A | c.667A>C p.T223P | Missense Mutation (SNP) | VAF 90/333 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as rs759233793; called by muse, mutect2, varscan2
- GHR | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100052171; called by muse, mutect2, varscan2
- HOXA13 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as rs1367909549; called by mutect2, varscan2
- IBTK | c.1049G>A p.G350E | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as rs1410131685; called by muse, mutect2, varscan2
- IGHV2-70 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs72690597; called by muse, varscan2
- KRTAP10-4 | c.107G>A p.C36Y | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1555923088; called by muse, mutect2
- MBD6 | c.1513C>T p.P505S | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.235); catalogued as rs769742075; called by muse, mutect2, varscan2
- OR5H15 | c.335G>T p.C112F | Missense Mutation (SNP) | VAF 78/245 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100736664; called by muse, mutect2, varscan2
- SPATA31E1 | c.3286G>A p.V1096M | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1307765542; called by muse, mutect2, varscan2
- TYW1B | c.1261G>A p.V421M | Missense Mutation (SNP) | VAF 45/274 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782374967; called by muse, mutect2, varscan2
- AKAP13 | c.3324A>G p.I1108M | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BORCS6 | c.913G>T p.D305Y | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDX1 | c.274C>A p.Q92K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.91); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- FBXW9 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- GDF10 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- IGHG1 | c.323_324del p.T108Mfs*8 | Frame Shift Del (DEL) | VAF 40/80 reads (50%) | called by pindel, varscan2
- IGHV2-70 | c.170_171insATG p.S56_W57ins* | Nonsense Mutation (INS) | VAF 38/115 reads (33%) | called by pindel, varscan2
- KRTAP10-6 | c.122G>A p.C41Y | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- LRP1B | c.4734T>A p.Y1578* | Nonsense Mutation (SNP) | VAF 35/84 reads (42%) | called by muse, mutect2, varscan2
- MPLKIP | c.431T>A p.M144K | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OR1C1 | c.767T>C p.I256T | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- PARD3 | c.2759G>A p.G920E | Missense Mutation (SNP) | VAF 61/126 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNCK | c.977G>A p.G326D (on ENST00000340888 / NM_001366975.1; = p.G409D on NM_001039582.3) | Missense Mutation (SNP) | VAF 28/30 reads (93%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAPGEF5 | c.1664C>T p.S555F (on ENST00000401957 / NM_001367602.2; = p.S858F on NM_012294.5) | Missense Mutation (SNP) | VAF 70/116 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RAPGEF5 | c.1663T>G p.S555A (on ENST00000401957 / NM_001367602.2; = p.S858A on NM_012294.5) | Missense Mutation (SNP) | VAF 69/117 reads (59%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RASGRF1 | c.2911A>G p.T971A | Missense Mutation (SNP) | VAF 17/191 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2
- ROCK2 | c.3116C>G p.A1039G | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SOCS6 | c.1088G>C p.S363T | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SRRT | c.122+2T>C p.X41_splice | Splice Site (SNP) | VAF 53/241 reads (22%) | called by muse, mutect2, varscan2
- STATH | c.103-3C>T | Splice Region (SNP) | VAF 115/245 reads (47%) | called by muse, mutect2, varscan2
- TTN | c.80834T>C p.I26945T (on ENST00000591111; = p.I19521T on NM_003319.4) | Missense Mutation (SNP) | VAF 86/191 reads (45%) | PolyPhen benign (0.079); called by muse, mutect2, varscan2
- TUT7 | c.1263G>T p.K421N | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGLV3-1 | c.288C>T p.T96= | Silent (SNP) | VAF 38/50 reads (76%) | catalogued as rs555994283; called by muse, varscan2
- IGLV3-1 | c.306T>A p.A102= | Silent (SNP) | VAF 38/46 reads (83%) | catalogued as rs538415293; called by muse, varscan2
- PIBF1 | c.466C>T p.L156= | Silent (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- USP27X | c.654C>T p.G218= | Silent (SNP) | VAF 65/78 reads (83%) | catalogued as rs1557162623, COSV71200938; called by muse, mutect2, varscan2
- ZNF302 | c.120G>T p.L40= | Silent (SNP) | VAF 17/126 reads (13%) | catalogued as rs1172844849; called by muse, mutect2, varscan2
- ZNF618 | c.39C>T p.D13= | Silent (SNP) | VAF 98/204 reads (48%) | catalogued as rs754153795, COSV55923540; called by muse, mutect2, varscan2
- AIP | c.-43A>G | 5'UTR (SNP) | VAF 45/139 reads (32%) | catalogued as rs772093310; called by muse, mutect2, varscan2
- AKAP13 | c.*3405T>C | 3'UTR (SNP) | VAF 24/98 reads (24%) | called by muse, mutect2, varscan2
- ARHGAP21 | c.4044+105G>A | Intron (SNP) | VAF 24/51 reads (47%) | catalogued as rs185311692; called by muse, mutect2, varscan2
- BRWD3 | c.-83del | 5'UTR (DEL) | VAF 47/74 reads (64%) | called by mutect2, pindel, varscan2
- CA5B | c.*523C>T | 3'UTR (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- CEP43 | c.*584T>A | 3'UTR (SNP) | VAF 27/74 reads (36%) | called by muse, mutect2, varscan2
- CKS1B | chr1:154974678 A>G | 5'Flank (SNP) | VAF 21/48 reads (44%) | called by muse, mutect2, varscan2
- CXCL13 | c.*179G>A | 3'UTR (SNP) | VAF 32/90 reads (36%) | called by muse, mutect2, varscan2
- DNAJC30 | c.*17A>G | 3'UTR (SNP) | VAF 80/441 reads (18%) | called by muse, mutect2, varscan2
- DUSP18 | c.*1354A>C | 3'UTR (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2, varscan2
- ENTPD5 | c.*2660T>A | 3'UTR (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- EXPH5 | c.*1015T>G | 3'UTR (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- FAM104A | c.*340_*344del | 3'UTR (DEL) | VAF 30/80 reads (38%) | catalogued as rs1218898271; called by mutect2, varscan2
- HAPLN1 | c.*1211C>A | 3'UTR (SNP) | VAF 22/115 reads (19%) | catalogued as rs1449786618; called by muse, mutect2, varscan2
- HLTF | c.-56G>C | 5'UTR (SNP) | VAF 21/87 reads (24%) | called by muse, mutect2, varscan2
- HNRNPD | c.-230T>C | 5'UTR (SNP) | VAF 34/79 reads (43%) | called by muse, mutect2, varscan2
- IGKC | c.*69T>C | 3'UTR (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- LHFPL2 | c.*457G>A | 3'UTR (SNP) | VAF 42/132 reads (32%) | catalogued as rs747977526; called by muse, mutect2, varscan2
- LHX9 | c.*4279C>A | 3'UTR (SNP) | VAF 33/100 reads (33%) | called by muse, mutect2, varscan2
- LPAR3 | c.*1221T>C | 3'UTR (SNP) | VAF 2/12 reads (17%) | called by muse, mutect2
- MCM4 | c.2366-76A>G | Intron (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- MITF | c.*1250G>A | 3'UTR (SNP) | VAF 67/104 reads (64%) | called by muse, mutect2, varscan2
- MS4A10 | c.*860G>A | 3'UTR (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2
- MUC19 | n.20663+708G>A | Intron (SNP) | VAF 42/98 reads (43%) | catalogued as rs1028374683; called by mutect2, varscan2
- NDUFA5 | c.22-58G>A | Intron (SNP) | VAF 249/552 reads (45%) | catalogued as rs780598273; called by muse, mutect2, varscan2
- NFIC | c.*50G>C | 3'UTR (SNP) | VAF 76/236 reads (32%) | called by muse, mutect2, varscan2
- NOTCH2NLC | chr1:149465067 T>A | 3'Flank (SNP) | VAF 21/65 reads (32%) | called by muse, mutect2, varscan2
- PEBP1 | chr12:118135926 C>G | 5'Flank (SNP) | VAF 10/31 reads (32%) | catalogued as rs1014349388; called by muse, mutect2
- PHEX | c.*2531G>C | 3'UTR (SNP) | VAF 21/23 reads (91%) | called by muse, mutect2, varscan2
- PNPLA7 | c.3767-165G>T | Intron (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2
- PPFIBP1 | c.-36+15751G>A | Intron (SNP) | VAF 38/83 reads (46%) | called by muse, mutect2, varscan2
- RBM38 | c.*686G>T | 3'UTR (SNP) | VAF 28/37 reads (76%) | called by muse, mutect2, varscan2
- SENP5 | c.*302T>C | 3'UTR (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- SGF29 | c.*36A>G | 3'UTR (SNP) | VAF 59/187 reads (32%) | catalogued as rs564172579; called by muse, mutect2, varscan2
- SLCO1A2 | c.*3366T>C | 3'UTR (SNP) | VAF 33/77 reads (43%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23955G>A | Intron (SNP) | VAF 12/37 reads (32%) | catalogued as rs530012100, COSV67450842; called by muse, mutect2, varscan2
- SNORD116-24 | chr15:25097865 G>C | 3'Flank (SNP) | VAF 18/125 reads (14%) | called by muse, mutect2, varscan2
- SNX17 | c.138+73C>T | Intron (SNP) | VAF 16/226 reads (7%) | catalogued as rs1324316307; called by muse, mutect2
- SUSD3 | c.*201G>A | 3'UTR (SNP) | VAF 8/108 reads (7%) | catalogued as rs1367272665; called by muse, mutect2
- TMEM178B | c.*6095del | 3'UTR (DEL) | VAF 62/149 reads (42%) | catalogued as rs1192971249; called by mutect2, pindel, varscan2
- TRIML2 | c.746-1019C>T | Intron (SNP) | VAF 14/37 reads (38%) | catalogued as rs1312702516; called by muse, mutect2, varscan2
- TTN | c.86930-43G>A | Intron (SNP) | VAF 36/89 reads (40%) | called by muse, mutect2, varscan2
- UVRAG | c.*719T>A | 3'UTR (SNP) | VAF 48/170 reads (28%) | called by muse, mutect2, varscan2
- WIPI2 | c.*1447C>T | 3'UTR (SNP) | VAF 35/132 reads (27%) | catalogued as rs371037715; called by muse, mutect2, varscan2
- ZER1 | c.*184del | 3'UTR (DEL) | VAF 4/42 reads (10%) | catalogued as rs746585169; called by mutect2, varscan2
